Somatic mutation profile of tumor specimen TARGET-10-PARJPL-09A (aliquot TARGET-10-PARJPL-09A-01D) from TARGET case TARGET-10-PARJPL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,374 days).
Specimen TARGET-10-PARJPL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3df0ee0b-8e76-4dfa-9fe4-1e999728bff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJPL-10A (Blood Derived Normal), aliquot TARGET-10-PARJPL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3355017c-6faf-4b2e-bf09-ddec4d59f84f

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AANAT | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV51686913; called by muse, mutect2, varscan2
- DPH2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1455953541, COSV52544347; called by muse, mutect2, varscan2
- LIN37 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV50001554; called by muse, mutect2, varscan2
- LOXL3 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs370672032; called by muse, mutect2, varscan2
- NCKAP5 | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.509); catalogued as COSV58484678; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- PCDHA8 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65340421, COSV65341310; called by muse, mutect2, varscan2
- PRR23B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs149871263, COSV100272065, COSV61494648; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SMARCA4 | c.3580G>A p.G1194R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1171822727, COSV60789775, COSV60800634; called by muse, mutect2, varscan2
- ZFHX4 | c.5048C>T p.P1683L | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs773314638, COSV51509010; called by muse, mutect2, varscan2
- HELZ2 | c.3609G>A p.A1203= (on ENST00000467148 / NM_001037335.2; = p.A634= on NM_033405.3) | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs751202427; called by muse, mutect2, varscan2
- RFC1 | c.522C>T p.V174= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- COL1A2 | c.3955-62C>T | Intron (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
